Somatic mutation profile of tumor specimen TCGA-WB-A81S-01A (aliquot TCGA-WB-A81S-01A-11D-A35I-08) from TCGA case TCGA-WB-A81S, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 59.1 years (21,587 days).
Specimen TCGA-WB-A81S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bac6654-201b-4c0c-917a-cfde1ef069a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81S-10A (Blood Derived Normal), aliquot TCGA-WB-A81S-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60806f41-d2be-4282-96c7-d8ae9a3fcb5d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC3 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs764638130; called by muse, mutect2, varscan2
- IGHG4 | c.983G>C p.*328Sext*35 | Nonstop Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs376149342; called by muse, mutect2, varscan2
- P4HTM | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV59086596; called by muse, mutect2, varscan2
- ZNF569 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241775801, COSV57599099; called by muse, mutect2, varscan2
- TSGA10 | c.728-2A>T p.X243_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- ANPEP | c.2481G>A p.K827= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- KMT2A | c.10071A>C p.S3357= | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- LAMA4 | c.3945C>T p.V1315= (on ENST00000230538 / NM_001105206.3; = p.V1308= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- PKD1L2 | c.297G>T p.T99= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
